Surgical pathology report (de-identified scan), TCGA case TCGA-14-0866, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0866-01B (Primary Tumor).

[page 1 of 2]
Report

* Final Report *

TCGA-14-0866

Document Type: AP Report
Document Date:
Document Status: Auth (Verified)
Document Title: Anatomic Pathology Report
Encounter info:

* Final Report *

Anatomic Pathology Report

Patient: Accession Number:
Patient Number: Date Collected:
Financial Number: Date Received:
Room/Bed: PT:
Admitting Physician:
Ordering Physician:

SURGICAL PATHOLOGY REPORT

AGNOSIS:

1. BRAIN, RIGHT TEMPORAL, BIOPSY, FS1A:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).
2. BRAIN, RIGHT TEMPORAL, BIOPSY:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

(Electronic Signature)

SPECIMEN:

1. Right temporal brain lesion,
2. Right temporal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

NAME OF OPERATION: Craniotomy, excision brain lesion.

PREOPERATIVE DIAGNOSIS: Right temporal brain lesion.

GROSS DESCRIPTION:

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
Report

* Final Report *

TCGA-14-0866

Received are two specimens.

Specimen #1 is received fresh labeled with the patient's name, hospital number and as "right temporal brain lesion". The specimen consists of a piece of white-tan, gelatinous soft tissue measuring 1.5 x 0.5 x 0.5 cm. The specimen is bisected and one half is submitted for intraoperative consultation and frozen section diagnosis and the remainder of the cryoblock is submitted in cassette "FS1A". The remainder of the tissue is submitted in cassette "1B".

Specimen #2 is received in formalin labeled with the patient's name, hospital number and as "right temporal brain lesion". The specimen consists of multiple fragments of soft, hemorrhagic tan tissue measuring 4.2 x 2.7 x 1.0 cm in aggregate. Multiple representative sections are submitted in cassettes labeled "2A" through "2E".

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: RIGHT TEMPORAL BRAIN LESION (FROZEN SECTION, TOUCH PREPARATION):
GLIOBLASTOMA MULTIFORME.

Pathologist:

TISSUE COMMITTEE CODE:

1

Fellow:

The pathologist has reviewed and interpreted the case with the resident/fellow.

ICD-9 CODES:

191.2

Page 1 (End of Report)

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file 4d983bdf-7a28-4d19-9dea-25143c9a831f (TCGA-14-0866.2C047C7B-EEDD-4FCC-BBFD-904DD7D45421.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).